Somatic mutation profile of tumor specimen C3L-00792-01 (aliquot CPT0015730006) from CPTAC case C3L-00792, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-00792-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c59f4de-2a7a-421b-99b3-3e1fbbaf7187.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00792-31 (Blood Derived Normal), aliquot CPT0018270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a16bc47-5b48-4dc5-b56a-e2f8b18cbb9a

The open-access MAF lists 85 somatic variants for this specimen: 68 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Nonsense Mutation 6, Splice Region 5, Frame Shift Del 4, Frame Shift Ins 3, Intron 2, Splice Site 1, RNA 1, 5'UTR 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRRS1L | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as rs878853280, CM166288, COSV73746916; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56239815; called by muse, mutect2, varscan2
- C3orf49 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); catalogued as rs752808341; called by muse, mutect2, varscan2
- C6orf132 | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1360342086; called by muse, mutect2
- CD163L1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs751654593, COSV58026045; called by muse, mutect2, varscan2
- DCST1 | c.63G>A p.T21= | Splice Region (SNP) | VAF 69/394 reads (18%) | catalogued as rs746329748; called by muse, mutect2, varscan2
- FASTKD1 | c.1078A>G p.K360E | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1304024983; called by muse, mutect2, varscan2
- FSD2 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV100575233; called by muse, mutect2, varscan2
- GRAP2 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 21/148 reads (14%) | catalogued as rs974232489, COSV59995807; called by muse, mutect2, varscan2
- KIF12 | c.1366C>T p.R456C (on ENST00000640217; = p.R318C on NM_138424.1) | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs774477975, COSV65117601; called by muse, mutect2, varscan2
- LRRC4B | c.429C>A p.D143E | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs1242459569; called by muse, mutect2, varscan2
- MFHAS1 | c.2558A>G p.Y853C | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1180605091; called by muse, mutect2
- MROH2B | c.4072C>G p.R1358G | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.933); catalogued as COSV101270595; called by muse, mutect2, varscan2
- PCDHGA12 | c.1886C>A p.A629E | Missense Mutation (SNP) | VAF 95/480 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs758701539, COSV52761643; called by muse, mutect2, varscan2
- PTPN5 | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 96/451 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100659538; called by muse, mutect2, varscan2
- RBMS1 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV62355996; called by muse, mutect2, varscan2
- SCN7A | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101313128; called by muse, mutect2, varscan2
- WDFY4 | c.7993G>C p.V2665L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.535); catalogued as rs200398332; called by muse, mutect2
- ZBTB39 | c.1556A>G p.D519G | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs769151317; called by muse, mutect2, varscan2
- ADAM12 | c.2367del p.R790Gfs*18 | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.2405T>C p.I802T | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ARID1A | c.4090C>T p.Q1364* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- ATXN7 | c.1409del p.P470Lfs*60 | Frame Shift Del (DEL) | VAF 48/206 reads (23%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- C3orf49 | c.262A>T p.T88S | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CD81 | c.561+3G>C | Splice Region (SNP) | VAF 81/435 reads (19%) | called by muse, mutect2, varscan2
- CDH8 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CENATAC | c.578+3A>T | Splice Region (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- CFAP77 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 79/308 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CHRM3 | c.501C>A p.Y167* | Nonsense Mutation (SNP) | VAF 52/274 reads (19%) | called by muse, mutect2, varscan2
- CLASRP | c.1707A>T p.K569N | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- COPZ1 | c.393A>T p.G131= | Splice Region (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- CUL4A | c.405dup p.N136* (on ENST00000375440 / NM_001008895.4; = p.N36* on NM_003589.3) | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- FAT1 | c.7631A>T p.E2544V | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FBXO38 | c.2090dup p.N697Kfs*44 | Frame Shift Ins (INS) | VAF 48/268 reads (18%) | called by mutect2, varscan2
- GOLGA6L2 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM2B | c.2671C>A p.Q891K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- KDM6B | c.3295C>A p.P1099T | Missense Mutation (SNP) | VAF 82/325 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KMT2D | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRWD1 | c.1705_1711del p.L569Gfs*16 | Frame Shift Del (DEL) | VAF 49/168 reads (29%) | called by mutect2, pindel, varscan2
- LUC7L3 | c.154C>G p.R52G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAGEB3 | c.469_475delinsC p.S157_N159delinsH | In Frame Del (DEL) | VAF 37/145 reads (26%) | called by pindel, varscan2*
- MKNK1 | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NAPSA | c.1172A>G p.K391R | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NBPF12 | c.496A>G p.N166D | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- NCOA2 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- NUMB | c.1394C>A p.P465Q (on ENST00000355058; = p.P454Q on NM_003744.5) | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- OR10G9 | c.235A>T p.M79L | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52J3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOF | c.3288+1G>C p.X1096_splice (on ENST00000272371 / NM_194248.3; = p.X349_splice on NM_004802.4) | Splice Site (SNP) | VAF 97/407 reads (24%) | called by muse, mutect2, varscan2
- PCSK1 | c.478G>T p.G160* | Nonsense Mutation (SNP) | VAF 81/527 reads (15%) | called by muse, mutect2, varscan2
- PDZD7 | c.1239dup p.E414* | Frame Shift Ins (INS) | VAF 18/135 reads (13%) | called by mutect2, pindel
- PPP1R9B | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- PROCA1 | c.344C>A p.S115Y (on ENST00000439862 / NM_001366301.1; = p.S87Y on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- RBM27 | c.1469A>T p.N490I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RIN1 | c.1651G>T p.D551Y | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RTCB | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUFY3 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SIPA1L2 | c.5092G>A p.E1698K | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SMCR8 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- SPG7 | c.10C>A p.L4M | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by mutect2, varscan2
- STXBP6 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, varscan2
- SYCP2L | c.1261A>G p.K421E | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- TICAM1 | c.1088_1089insCCC p.P367dup | In Frame Ins (INS) | VAF 26/170 reads (15%) | called by pindel, varscan2
- TMEM151A | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TRO | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UNC13D | c.2447+6T>C | Splice Region (SNP) | VAF 36/145 reads (25%) | called by muse, mutect2, varscan2
- VHL | c.422del p.N141Mfs*18 | Frame Shift Del (DEL) | VAF 73/254 reads (29%) | called by mutect2, pindel, varscan2
- AOPEP | c.189C>T p.A63= | Silent (SNP) | VAF 33/166 reads (20%) | called by muse, mutect2, varscan2
- CSF3 | c.372C>T p.A124= | Silent (SNP) | VAF 29/229 reads (13%) | catalogued as rs769044135; called by muse, mutect2, varscan2
- HEPHL1 | c.273C>A p.I91= | Silent (SNP) | VAF 57/336 reads (17%) | called by muse, mutect2, varscan2
- IGSF9B | c.1590A>G p.E530= | Silent (SNP) | VAF 44/221 reads (20%) | called by muse, mutect2, varscan2
- KRTAP9-4 | c.75G>A p.K25= | Silent (SNP) | VAF 50/302 reads (17%) | called by muse, mutect2, varscan2
- MUC17 | c.12150A>G p.E4050= | Silent (SNP) | VAF 43/206 reads (21%) | called by muse, mutect2, varscan2
- NRK | c.3465G>A p.G1155= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs770125167, COSV54596902; called by muse, mutect2, varscan2
- PUM3 | c.771C>T p.Y257= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs139189443, COSV67395982; called by muse, mutect2, varscan2
- TRAF3IP2 | c.348T>G p.P116= | Silent (SNP) | VAF 46/205 reads (22%) | called by muse, mutect2, varscan2
- TSNARE1 | c.921G>A p.K307= | Silent (SNP) | VAF 23/221 reads (10%) | called by muse, mutect2, varscan2
- UTS2R | c.18G>A p.E6= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs757493964; called by muse, varscan2
- XRN1 | c.1134A>G p.A378= | Silent (SNP) | VAF 64/237 reads (27%) | called by muse, mutect2, varscan2
- DMAC2 | chr19:41440176 del GCAACATA | 5'Flank (DEL) | VAF 41/156 reads (26%) | called by mutect2, pindel, varscan2
- HLA-V | n.96_97insA | RNA (INS) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- MRTFB | c.155-23271del | Intron (DEL) | VAF 50/206 reads (24%) | called by mutect2, pindel, varscan2
- VCP | c.2161-48C>A | Intron (SNP) | VAF 46/210 reads (22%) | called by muse, mutect2
- ZFPM2 | c.-39G>A | 5'UTR (SNP) | VAF 26/109 reads (24%) | called by muse, varscan2
